Somatic mutation profile of tumor specimen C3L-00604-01 (aliquot CPT0063810006) from CPTAC case C3L-00604, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.1 years (22,335 days).
Specimen C3L-00604-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 635891a3-3af0-4a3d-bd0e-bb38843c015f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00604-31 (Blood Derived Normal), aliquot CPT0065330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d030c90a-7b6a-482d-854f-7fe7c6f6776e

The open-access MAF lists 60 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Intron 5, 5'UTR 2, Splice Region 2, 3'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 175/568 reads (31%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 49/170 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAAS | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 156/456 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as rs1395116769, CD030570, COSV99267072; called by muse, mutect2, varscan2
- ABCC8 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 79/580 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100217012, COSV56851438; called by muse, mutect2, varscan2
- CNTNAP2 | c.3347A>G p.N1116S | Missense Mutation (SNP) | VAF 14/430 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as rs763650919; called by muse, mutect2
- CYP1A2 | c.872G>C p.S291T | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.053); catalogued as COSV59659931; called by muse, mutect2, varscan2
- EDN1 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 109/368 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs764236555; called by muse, mutect2, varscan2
- MAGEC2 | c.707T>A p.V236E | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56000824; called by muse, mutect2, varscan2
- OR5M8 | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769527019; called by muse, mutect2, varscan2
- RECK | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100937706; called by muse, mutect2, varscan2
- SAMD13 | c.157G>A p.V53M (on ENST00000370671; = p.V47M on NM_001010971.3) | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1304943628; called by muse, mutect2, varscan2
- SELENOO | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs369750052; called by muse, mutect2, varscan2
- SLC2A4 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 61/450 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1243626579, COSV99142712; called by muse, mutect2, varscan2
- SLC5A3 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62973469; called by muse, mutect2, varscan2
- TRIM64C | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1379722418, COSV73267303; called by muse, mutect2
- TRPM6 | c.5356G>A p.V1786I | Missense Mutation (SNP) | VAF 120/512 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs142946646, COSV62520097, COSV62521179; called by muse, mutect2, varscan2
- AKR1B1 | c.67-7C>T | Splice Region (SNP) | VAF 124/441 reads (28%) | called by muse, mutect2, varscan2
- ANKRD17 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CCDC136 | c.2960T>G p.M987R | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CUL4B | c.1642T>G p.F548V | Missense Mutation (SNP) | VAF 7/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPPA2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.287); called by muse, mutect2
- ERCC6 | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- EZH2 | c.1891C>T p.P631S (on ENST00000460911 / NM_001203247.2; = p.P636S on NM_004456.5) | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GTF3C2 | c.1835A>G p.H612R | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- HES5 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- HOOK3 | c.1694A>T p.K565M | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM2A | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.601); called by muse, mutect2
- KRTAP10-4 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 74/668 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- MAGEB5 | c.217A>G p.R73G | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- RBM39 | c.1381A>T p.I461F (on ENST00000253363 / NM_001323424.2; = p.I455F on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RNF144B | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SIX2 | c.828C>G p.D276E | Missense Mutation (SNP) | VAF 56/441 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- TAF1L | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TXNIP | c.1141-5T>G | Splice Region (SNP) | VAF 72/227 reads (32%) | called by muse, mutect2, varscan2
- ZNF257 | c.1232G>C p.W411S | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- ADD2 | c.1014G>A p.R338= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- AHNAK | c.16191C>T p.S5397= | Silent (SNP) | VAF 19/204 reads (9%) | catalogued as rs763437094; called by muse, mutect2
- COBL | c.2235C>A p.T745= | Silent (SNP) | VAF 90/249 reads (36%) | catalogued as rs145708533; called by muse, mutect2, varscan2
- CTTNBP2 | c.3702C>T p.S1234= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs780731601, COSV50389650; called by muse, mutect2, varscan2
- DLGAP2 | c.2421C>T p.S807= | Silent (SNP) | VAF 16/255 reads (6%) | catalogued as rs755621517, COSV70097775; called by muse, mutect2
- GNA14 | c.276G>A p.T92= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as rs781490674, COSV59029091; called by muse, mutect2, varscan2
- HACE1 | c.1812G>T p.L604= | Silent (SNP) | VAF 69/297 reads (23%) | catalogued as COSV53502514; called by muse, mutect2, varscan2
- LECT2 | c.201C>T p.Y67= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as rs138349831; called by muse, mutect2, varscan2
- MICAL3 | c.1422C>T p.I474= | Silent (SNP) | VAF 75/207 reads (36%) | called by muse, mutect2, varscan2
- MUC22 | c.4740G>A p.T1580= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as rs1016024607; called by muse, mutect2, varscan2
- NAALADL1 | c.408C>T p.N136= | Silent (SNP) | VAF 80/204 reads (39%) | catalogued as rs373082652; called by muse, mutect2, varscan2
- OR2C3 | c.270G>A p.Q90= | Silent (SNP) | VAF 114/479 reads (24%) | called by muse, mutect2, varscan2
- PTK7 | c.2268C>T p.N756= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as rs764023682; called by muse, mutect2, varscan2
- TRANK1 | c.927G>T p.T309= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, varscan2
- VPS51 | c.648G>T p.L216= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- ZBED9 | c.504G>A p.Q168= | Silent (SNP) | VAF 45/193 reads (23%) | catalogued as rs1299181365; called by muse, mutect2, varscan2
- ACE | c.3692-40G>T | Intron (SNP) | VAF 140/297 reads (47%) | called by muse, mutect2, varscan2
- ANXA6 | c.*16G>T | 3'UTR (SNP) | VAF 39/182 reads (21%) | called by muse, mutect2, varscan2
- MAGEC3 | c.910-517G>A | Intron (SNP) | VAF 49/142 reads (35%) | catalogued as rs977303461, COSV68924151; called by muse, mutect2, varscan2
- PRSS21 | c.-15G>A | 5'UTR (SNP) | VAF 12/125 reads (10%) | catalogued as rs1030054132; called by muse, mutect2, varscan2
- RABGGTB | c.-11C>A | 5'UTR (SNP) | VAF 64/153 reads (42%) | called by mutect2, varscan2
- SPOCK2 | c.189+1258C>T | Intron (SNP) | VAF 44/217 reads (20%) | called by muse, mutect2, varscan2
- SRGAP2 | c.1353+59A>G | Intron (SNP) | VAF 6/49 reads (12%) | called by mutect2, varscan2
- SRPK1 | c.1691-346C>G | Intron (SNP) | VAF 22/244 reads (9%) | catalogued as COSV60416211; called by muse, mutect2
- TFE3 | c.*401T>G | 3'UTR (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
